Somatic mutation profile of tumor specimen 0E1NZX from CCDI case PBCWJE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1NZX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a692fa4-5e1b-4e43-af2b-9087b143a2d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1NYP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3ec1e34-b6b2-4a2b-8287-efcd9d70a89c

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSN | c.1227C>A p.D409E | Missense Mutation (SNP) | VAF 63/172 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.038); catalogued as COSV100814242; called by muse, mutect2, varscan2
- RTN1 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1411360982; called by muse, mutect2, varscan2
- SLC9A4 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs768860169, COSV54829958; called by muse, mutect2, varscan2
- DOCK11 | c.1886T>A p.M629K | Missense Mutation (SNP) | VAF 134/360 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CARTPT | c.249C>T p.D83= | Silent (SNP) | VAF 32/168 reads (19%) | catalogued as rs776155749; called by mutect2, varscan2
- AC006530.1 | n.555del | RNA (DEL) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- PCDH19 | c.-63C>T | 5'UTR (SNP) | VAF 3/17 reads (18%) | catalogued as rs892613445; called by muse, varscan2
